Somatic mutation profile of tumor specimen TCGA-D8-A1JL-01A (aliquot TCGA-D8-A1JL-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.5 years (26,484 days).
Specimen TCGA-D8-A1JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 683b04ba-a405-4d9f-a24a-3b8bceb49010.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JL-10A (Blood Derived Normal), aliquot TCGA-D8-A1JL-10A-01D-A188-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17fc7cb7-4390-44ad-ba8b-b4f7ac697cf1

The open-access MAF lists 116 somatic variants for this specimen: 84 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 29, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 3, Intron 3, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 48/109 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANGEL1 | c.808C>G p.P270A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as COSV51871852; called by muse, mutect2, varscan2
- ARFGEF1 | c.4798A>G p.S1600G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51602661; called by muse, mutect2, varscan2
- ARHGAP15 | c.999C>A p.N333K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54478696; called by muse, mutect2, varscan2
- ARHGAP24 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV67828613; called by muse, mutect2, varscan2
- ARHGEF35 | c.1391C>A p.S464Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65312402; called by muse, mutect2, varscan2
- ATRX | c.5173A>T p.K1725* | Nonsense Mutation (SNP) | VAF 17/167 reads (10%) | catalogued as COSV100971254; called by muse, mutect2, varscan2
- BAZ2B | c.4889G>A p.G1630E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100600879; called by muse, mutect2, varscan2
- BCL11B | c.2648C>A p.T883N (on ENST00000357195 / NM_001282237.2; = p.T812N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as COSV61733362; called by muse, mutect2, varscan2
- BIRC6 | c.11594C>T p.T3865I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV70195612; called by muse, mutect2, varscan2
- CDC20 | c.1429C>G p.P477A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60521659; called by muse, mutect2, varscan2
- CDH7 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59881646, COSV59895818; called by muse, mutect2, varscan2
- CDK1 | c.684G>C p.W228C | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100358894; called by muse, mutect2
- CDS1 | c.410A>T p.Y137F | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55686613; called by muse, mutect2, varscan2
- CELF2 | c.757-1G>A p.X253_splice (on ENST00000416382 / NM_001025077.3; = p.X260_splice on NM_006561.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 84/238 reads (35%) | catalogued as COSV100258069; called by muse, mutect2, varscan2
- CENPE | c.6112G>C p.A2038P | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.806); catalogued as COSV54376243; called by muse, mutect2, varscan2
- CFH | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as CM1512029, COSV62776330; called by muse, mutect2, varscan2
- CHD2 | c.3752G>A p.R1251H | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs748103788, COSV67706750; called by muse, mutect2, varscan2
- CPED1 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936142278, COSV59996515; called by muse, mutect2, varscan2
- CPVL | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV55299304; called by muse, mutect2, varscan2
- CSMD1 | c.3059A>G p.Q1020R (on ENST00000520002; = p.Q1019R on NM_033225.6) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV59283078; called by muse, mutect2, varscan2
- DNAH3 | c.10681A>G p.I3561V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as rs1284284303, COSV54503785; called by muse, mutect2, varscan2
- DPYSL5 | c.1065G>C p.M355I | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99982650; called by muse, mutect2
- DYRK4 | c.1176C>A p.D392E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV50537838, COSV50539140; called by muse, mutect2, varscan2
- EFCAB14 | c.987+2T>G p.X329_splice | Splice Site (SNP) | VAF 59/159 reads (37%) | catalogued as COSV100905655; called by muse, mutect2, varscan2
- EIF2AK4 | c.3791A>C p.K1264T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55465103; called by muse, mutect2, varscan2
- ESYT2 | c.2215A>T p.S739C (on ENST00000613624; = p.S663C on NM_020728.3) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV99277116; called by muse, mutect2
- FBXO10 | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV52831450; called by muse, mutect2, varscan2
- FLG | c.7595C>T p.S2532L | Missense Mutation (SNP) | VAF 309/572 reads (54%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.497); catalogued as rs756739106, COSV64236669; called by muse, mutect2, varscan2
- GRM8 | c.2720C>G p.S907* | Nonsense Mutation (SNP) | VAF 47/302 reads (16%) | catalogued as COSV58802790; called by muse, mutect2, varscan2
- HECW2 | c.4460G>T p.R1487I | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53649803, COSV53662198; called by muse, mutect2, varscan2
- HYOU1 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68215155; called by muse, mutect2, varscan2
- IL6ST | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV61139748, COSV61143270; called by muse, mutect2, varscan2
- KAT6B | c.1786C>G p.R596G | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.987); catalogued as COSV54742347, COSV54745394; called by muse, mutect2
- KCND2 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV58569741; called by muse, mutect2, varscan2
- KDM3A | c.3685C>G p.Q1229E | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs1012310873, COSV57218054, COSV57218797; called by muse, mutect2, varscan2
- KDM7A | c.1831A>G p.R611G | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99134919; called by muse, mutect2, varscan2
- KIF27 | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52825157; called by muse, mutect2, varscan2
- KNTC1 | c.6377G>C p.S2126T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV61078906; called by muse, mutect2, varscan2
- KRT20 | c.1010C>A p.A337D | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV51423993; called by muse, mutect2, varscan2
- LACTB | c.660T>G p.I220M | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99979023; called by muse, mutect2, varscan2
- LMOD1 | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV66171859; called by muse, mutect2, varscan2
- MAP2 | c.4525G>A p.A1509T | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV52281464; called by muse, mutect2, varscan2
- MBD3L1 | c.466A>C p.K156Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as COSV59775732; called by muse, mutect2, varscan2
- MCF2L | c.2839C>G p.Q947E (on ENST00000375608; = p.Q915E on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56175445; called by muse, mutect2, varscan2
- MOV10 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV62490717; called by muse, mutect2, varscan2
- MYH8 | c.4358A>G p.D1453G | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959991; called by muse, mutect2, varscan2
- MYT1 | c.3205C>A p.Q1069K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV60501225; called by muse, mutect2, varscan2
- OR10G9 | c.395C>A p.T132N | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as COSV66685741; called by muse, mutect2, varscan2
- OR6T1 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV58305666; called by mutect2, varscan2
- PABPN1L | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV56350941; called by muse, mutect2, varscan2
- PARP1 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV64687760; called by muse, mutect2, varscan2
- PCDHB1 | c.825A>T p.K275N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV60629482; called by muse, mutect2, varscan2
- PLCL1 | c.1645G>C p.D549H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV70821223; called by mutect2, varscan2
- POLR3D | c.647C>G p.A216G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60570517; called by muse, mutect2, varscan2
- RAB37 | c.183G>A p.T61= | Splice Region (SNP) | VAF 14/92 reads (15%) | catalogued as rs759047469, COSV61192454; called by muse, mutect2, varscan2
- RAD51AP2 | c.2893A>G p.K965E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV67587324; called by muse, mutect2, varscan2
- RBP4 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs766365350, COSV65159613; called by muse, mutect2, varscan2
- RELN | c.8800G>T p.V2934L | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.576); catalogued as COSV100634484; called by muse, mutect2
- RIMBP2 | c.307+1G>C p.X103_splice | Splice Site (SNP) | VAF 7/11 reads (64%) | catalogued as COSV55464813; called by muse, mutect2, varscan2
- SCN2A | c.5281A>T p.I1761F | Missense Mutation (SNP) | VAF 100/231 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV51832630; called by muse, mutect2, varscan2
- SHB | c.1235A>C p.H412P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66628427; called by muse, mutect2, varscan2
- SLC17A8 | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 33/161 reads (20%) | catalogued as COSV60121908; called by muse, mutect2, varscan2
- SLC22A11 | c.949A>C p.M317L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100102566; called by muse, mutect2
- SMOC2 | c.1039C>G p.L347V (on ENST00000356284 / NM_001166412.2; = p.L358V on NM_022138.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62433930; called by muse, mutect2, varscan2
- SNX32 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs781557193, COSV100362575, COSV57448950, COSV57449181; called by mutect2, varscan2
- SPTBN1 | c.3913G>T p.E1305* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV61685634; called by muse, mutect2, varscan2
- STK17A | c.612G>C p.K204N | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60046574; called by muse, mutect2
- STT3B | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as rs751562865, COSV55501227; called by muse, mutect2, varscan2
- TAOK3 | c.1603C>A p.Q535K | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.109); catalogued as COSV66824801; called by muse, mutect2, varscan2
- TMEM245 | c.1954C>A p.L652I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.636); catalogued as COSV65821892; called by muse, mutect2, varscan2
- TWF1 | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV57299982; called by muse, mutect2, varscan2
- URB2 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1247118198, COSV50981311; called by muse, mutect2, varscan2
- WNT2B | c.379G>A p.V127I (on ENST00000369684 / NM_024494.3; = p.V108I on NM_004185.4) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs140255509; called by muse, mutect2, varscan2
- ZNF644 | c.3787T>A p.C1263S (on ENST00000337393 / NM_201269.3; = p.C41S on NM_016620.3) | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61346051; called by muse, mutect2, varscan2
- ZNF682 | c.673G>T p.G225* | Nonsense Mutation (SNP) | VAF 26/144 reads (18%) | catalogued as COSV62066092; called by muse, mutect2, varscan2
- ADGRL2 | c.1870_1877del p.S624Tfs*6 (on ENST00000370717 / NM_001366005.1; = p.S611Tfs*6 on NM_012302.4) | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel
- DMXL2 | c.2470_2481delinsAA p.Q824Kfs*13 | Frame Shift Del (DEL) | VAF 30/180 reads (17%) | called by pindel, varscan2*
- DNAH10 | c.10998_11002del p.N3667Afs*57 (on ENST00000409039; = p.N3606Afs*57 on NM_207437.3) | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel, varscan2
- EIF2B5 | c.1334_1350del p.V445Afs*3 (on ENST00000647909; = p.V437Afs*3 on NM_003907.3) | Frame Shift Del (DEL) | VAF 12/132 reads (9%) | called by mutect2, pindel
- GABPA | c.1214C>T p.T405I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2
- MRC1 | c.3395G>C p.S1132T | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PXDNL | c.2976_2989del p.W992Cfs*24 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, varscan2
- RPL8 | c.332_333insCC p.I112Qfs*38 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- ABLIM1 | c.1050G>A p.R350= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1005601206, COSV53299943; called by muse, mutect2, varscan2
- AC244197.3 | c.447A>C p.I149= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV61711256; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3076T>C p.L1026= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV54436739; called by muse, mutect2, varscan2
- AXDND1 | c.30G>T p.P10= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV62639775; called by muse, mutect2, varscan2
- CCDC50 | c.831C>T p.P277= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV66667205; called by muse, mutect2, varscan2
- CDHR1 | c.1386C>G p.L462= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV60559623; called by muse, mutect2, varscan2
- DNAH5 | c.11616C>T p.I3872= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs773699669, COSV54204663; called by muse, mutect2, varscan2
- DNAH7 | c.7983C>T p.I2661= | Silent (SNP) | VAF 59/169 reads (35%) | catalogued as COSV56752273; called by muse, mutect2, varscan2
- ERICH3 | c.4047G>T p.T1349= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as rs759546243, COSV58599440; called by muse, mutect2, varscan2
- FUT4 | c.1269C>A p.T423= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV62468888; called by muse, mutect2, varscan2
- GPR174 | c.708A>G p.A236= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV52131548; called by muse, mutect2, varscan2
- HLA-C | c.273C>T p.Y91= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV66110527; called by muse, mutect2, varscan2
- HOATZ | c.102C>G p.A34= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV60440582; called by muse, mutect2, varscan2
- HOXA13 | c.888G>C p.A296= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV56082867; called by muse, mutect2, varscan2
- HTR6 | c.315C>T p.F105= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs200417532, COSV57032202; called by muse, mutect2
- LPP | c.1446C>G p.P482= | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as COSV57079441; called by muse, mutect2, varscan2
- RHOBTB2 | c.213C>T p.D71= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs760989514, COSV52569731; called by muse, mutect2, varscan2
- RNASE7 | c.180G>A p.K60= | Silent (SNP) | VAF 51/108 reads (47%) | catalogued as COSV53876742; called by muse, mutect2, varscan2
- SERPIND1 | c.411C>T p.L137= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV53138247, COSV99300380; called by muse, mutect2, varscan2
- SLC13A2 | c.774C>A p.G258= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV58992601; called by muse, mutect2, varscan2
- SLC25A3 | c.504C>T p.A168= (on ENST00000228318 / NM_005888.3; = p.A167= on NM_002635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV99499507; called by muse, mutect2
- SLC2A12 | c.765C>T p.S255= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs1302517402, COSV51597734; called by muse, mutect2, varscan2
- TGFB3 | c.240G>T p.L80= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as COSV53168961; called by muse, mutect2, varscan2
- TMPRSS15 | c.2290C>A p.R764= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV53034964; called by muse, mutect2, varscan2
- UBE3C | c.1548T>C p.D516= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV100780034; called by muse, mutect2, varscan2
- UBR4 | c.3816T>G p.T1272= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV64382981; called by muse, mutect2, varscan2
- VCAM1 | c.924T>A p.V308= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as COSV54117827; called by muse, mutect2, varscan2
- WNT2 | c.465T>C p.G155= | Silent (SNP) | VAF 56/201 reads (28%) | catalogued as COSV55409614; called by muse, mutect2, varscan2
- ZNF682 | c.90G>A p.R30= | Silent (SNP) | VAF 30/283 reads (11%) | catalogued as COSV62068491; called by muse, mutect2, varscan2
- AGBL4 | c.1267+22C>T | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- CR1 | c.487+12078G>A | Intron (SNP) | VAF 34/176 reads (19%) | catalogued as COSV65455980; called by muse, mutect2, varscan2
- GCNT2 | c.925+27505A>T | Intron (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100297360; called by muse, mutect2, varscan2
